Somatic mutation profile of tumor specimen TCGA-06-0132-01A (aliquot TCGA-06-0132-01A-02D-1491-08) from TCGA case TCGA-06-0132, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.6 years (18,125 days).
Specimen TCGA-06-0132-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f7ee9e65-3450-4121-858c-9c2901f20603.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0132-10A (Blood Derived Normal), aliquot TCGA-06-0132-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f70a963-4852-4ee0-87e4-71046603b63d

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 16, Silent 7, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG4 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs571213849, COSV56644514; called by muse, mutect2, varscan2
- CACNA1S | c.4861G>A p.V1621I | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs756066219, COSV62941468; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHL1 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs751043648, COSV56597627; called by muse, mutect2, varscan2
- FCRLA | c.890C>T p.P297L (on ENST00000367959; = p.P274L on NM_032738.4) | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1233441071, COSV52686835; called by muse, mutect2
- FOXN4 | c.1268C>T p.P423L | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770392574, COSV54495705; called by muse, mutect2, varscan2
- NLRP12 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 48/425 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs199512582, COSV60744876, COSV60744973; called by muse, mutect2, varscan2
- OR9K2 | c.833G>A p.G278D (on ENST00000305377; = p.G256D on NM_001005243.1) | Missense Mutation (SNP) | VAF 41/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59532396, COSV59532520; called by muse, mutect2, varscan2
- PDE4DIP | c.7022C>T p.P2341L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs148370554; called by muse, varscan2
- PIP5K1B | c.1493A>C p.Y498S | Missense Mutation (SNP) | VAF 33/240 reads (14%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV55252104; called by muse, mutect2, varscan2
- PSMA5 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54749076; called by muse, mutect2, varscan2
- SCN3A | c.920A>T p.N307I | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs769845100, COSV51815710; called by muse, mutect2
- SCN9A | c.5479G>T p.D1827Y (on ENST00000303354; = p.D1816Y on NM_002977.3) | Missense Mutation (SNP) | VAF 29/229 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1399942162, COSV57602789, COSV57615643; called by muse, mutect2, varscan2
- SERPINA12 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57944687; called by mutect2, varscan2
- SPAG17 | c.867A>G p.I289M | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs1434976723, COSV60462599; called by muse, mutect2, varscan2
- SUSD1 | c.1624A>G p.N542D | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV62584551; called by muse, mutect2, varscan2
- YIPF4 | c.626G>A p.S209N | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV53214153; called by muse, mutect2, varscan2
- ZBTB20 | c.1563del p.K522Sfs*19 (on ENST00000474710 / NM_001164342.2; = p.K449Sfs*19 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 12/109 reads (11%) | catalogued as COSV61848428; called by mutect2, pindel, varscan2
- CAMTA1 | c.1390C>T p.L464= | Silent (SNP) | VAF 24/163 reads (15%) | catalogued as COSV57911910; called by muse, varscan2
- CFAP47 | c.4728G>A p.S1576= | Silent (SNP) | VAF 19/113 reads (17%) | catalogued as rs528323979, COSV57975080; called by muse, mutect2, varscan2
- LAMB1 | c.3378C>T p.D1126= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as rs759130532, COSV55963615, COSV55967053; called by muse, mutect2, varscan2
- MBD5 | c.4158C>T p.G1386= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs543329958, COSV68698171; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- PCDHA9 | c.1509G>A p.S503= | Silent (SNP) | VAF 15/150 reads (10%) | catalogued as rs782166017, COSV65324248; called by muse, mutect2
- RAB11FIP5 | c.1005G>A p.S335= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs1455520614, COSV50248290; called by muse, mutect2, varscan2
- SPOCK3 | c.1224T>C p.I408= | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as COSV62730324; called by muse, mutect2, varscan2
